Surgical pathology report (de-identified scan), TCGA case TCGA-24-0979, project TCGA-OV (Ovarian Serous Cystadenocarcinoma), tissue source site Washington University, specimen TCGA-24-0979-01A (Primary Tumor).

[page 1 of 3]
Surgical Pathology Report

Final

SURGICAL PATHOLOGY REPORT

Physician(s):

Other Related Clinical Data:

DIAGNOSIS:

OVARY, RIGHT, SALPINGO-OOPHORECTOMY

- POORLY DIFFERENTIATED PAPILLARY SEROUS ADENOCARCINOMA

- ADENOCARCINOMA IS PRESENT ON THE OVARIAN SURFACE

FALLOPIAN TUBE, RIGHT, SALPINGO-OOPHORECTOMY

- METASTATIC ADENOCARCINOMA INVOLVING PERITUBAL SOFT TISSUE

OVARY, LEFT, SALPINGO OOPHORECTOMY

- POORLY DIFFERENTIATED PAPILLARY SEROUS ADENOCARCINOMA

- ADENOCARCINOMA IS PRESENT ON THE OVARIAN SURFACE

FALLOPIAN TUBE, LEFT, SALPINGO OOPHORECTOMY

- METASTATIC ADENOCARCINOMA INVOLVING PERITUBAL SOFT TISSUE

- PERITUBAL PARAMESONEPHRIC CYST

UTERUS, CERVIX, TOTAL ABDOMINAL HYSTERECTOMY

- NO HISTOPATHOLOGIC ABNORMALITY

UTERUS, ENDOMETRIUM, TOTAL ABDOMINAL HYSTERECTOMY

- PROLIFERATIVE ENDOMETRIUM

UTERUS, MYOMETRIUM, TOTAL ABDOMINAL HYSTERECTOMY

- LEIOMYOMATA, 1.9 CM IN GREATEST DIMENSION

- ADENOMYOSIS

UTERUS, SEROSA, TOTAL ABDOMINAL HYSTERECTOMY

- EXTENSIVE ADHESIONS ASSOCIATED WITH METASTATIC PAPILLARY SEROUS

ADENOCARCINOMA

RECTOSIGMOID TUMOR FLAP, EXCISION

- METASTATIC PAPILLARY SEROUS ADENOCARCINOMA

GASTRO COLIC OMENTUM, OMENTECTOMY

- METASTATIC PAPILLARY SEROUS ADENOCARCINOMA

By this signature, I attest that the above diagnosis is
based upon my personal
examination of the slides (and/or other material indicated in the
diagnosis).

M.D.

***Report Electronically Reviewed and Signed Out By

[page 2 of 3]
**

Intraoperative Consultation:

"Called to pick-up '#1 uterus, cervix, BSO,' consisting of uterus (11 x 6 x 3.5 cm), right ovary (6 x 3 x 1.5 cm), right fallopian tube (6 cm), left ovary (3.5 x 3 x 2 cm), left fallopian tube (5 cm), weighing 198 grams. The right ovary is replaced by a gray-tan fleshy nodule with gross apparently intact capsule. The left ovary is also replaced by a fleshy mass with papillary projections on the surface grossly. The anterior segment of the uterus is thickened by gray-tan tissue. The uterus is opened to show a 4 x 2.5 cm endometrial cavity with unremarkable endometrium. Leiomyomata are identified. Tumor and normal tissue are sampled for study from the right ovary. Tissue taken for tumor bank from right ovary. Rest for permanents," by

Microscopic Description and Comment:

Microscopic examination substantiates the above cited diagnosis.

History:

The patient is a year old woman with peritoneal fluid positive for adenocarcinoma), CA125 greater than 1000, and an ovarian mass.

Specimen(s) Received:

- A: UTERUS, CERVIX, BILATERAL TUBES AND OVARIES
- B: RECTAL-SIGMOID TUMOR FLAP
- C: GASTRO COLIC OMENTUM

Gross Description

The specimens are received in three formalin-filled containers, each labeled "BSO." The first container is further labeled "uterus, cervix, 11 cm in length x 6 cm from cornu to cornu x 3.5 cm anterior to posterior. The serosal surface of the uterus is brown to black with adhesions and yellow-tan plaques, measuring 1.5 cm and 1.1 cm in greatest dimension, on the anterior surface of the uterus. The 4 x 3 cm tan exocervix has multiple pinpoint areas of dark red congestion. The 2.5 cm long endocervical canal is lined by tan mucosa and has scattered Nabothian cysts, measuring from 0.2 cm to 0.5 cm in greatest dimension. The endometrial cavity measures 4 x 2.5 cm with unremarkable mucosa. The myometrium contains six well circumscribed, tan-white lesions with firm whorled cut surfaces, free of hemorrhage and necrosis, measuring 0.2 cm, 0.7 cm, 1.9 cm, and 1.5 cm, 0.6 cm, and 0.4 cm in greatest dimensions. The non-myomatous myometrium measures 1.7 cm in greatest thickness. The right ovary measures 6 x 3 x 1.5 cm and is replaced by gray-tan fleshy nodular masses. The right fallopian tube measures 6 cm in length x 0.6 cm in diameter, with adhesions. Two metal clips are identified at tube-uterus junction. The left ovary measures 3.5 x 3 x 2 cm and is also replaced by gray-tan nodular masses. The left fallopian tube measures 5 cm in length x 0.6 cm in diameter, with serosal adhesions. Two metal clips are noted at the tube and uterine junction. They are labeled A1 - anterior cervix, A2 - posterior cervix; A3 - anterior endometrium; A4 - posterior endometrium; A5, A6 - anterior uterus with plaque and white-tan lesion; A7, A8 - right ovary; A9 - right ovary with hilar area; A10 - right fallopian tube; A11, A12 - left ovary; A13 - left fallopian tube; A14 - additional section of uterus, adjacent to the right ovary. Jar 2.

The second container is labeled "recto-sigmoid tumor flap." It contains multiple fragments of white tan tissue, ranging from 0.9 x 0.8 x 0.5 cm, to 3 x 2.5 x 1.6 cm. Some of these fragments have polypoid white-tan surfaces. Labeled B1 and B2. Jar 1.

The third container is labeled "gastro-colonic omentum." It contains a firm

[page 3 of 3]
nodular omentum measuring 26 x 16 x 2.8 cm in greatest dimension. The specimen is completely replaced by white-tan, firm tumor intermixed with yellow adipose tissue. Labeled C1 to C3. Jar 4.

Synopsis

SYNOPTIC REPORTING FORM FOR MALIGNANT OVARIAN NEOPLASMS

1. The HISTOLOGIC DIAGNOSIS is:
Serous adenocarcinoma
2. The LOCATION(S) OF THE PRIMARY TUMOR(S) is/are:
Right and left ovary (synchronous primary tumors)
3. HISTOLOGIC GRADE (G):
G3-G4 (Poorly differentiated or undifferentiated)
4. Tumor IS identified on the ovarian surface(s).
5. Metastatic involvement of the omentum is PRESENT.
6. The maximum dimension of tumor implants outside the true pelvis is:
> 2 cm
7. Regional lymph node metastases CANNOT BE EVALUATED.
8. The total number of regional lymph nodes examined is 0.
9. The total number of metastatically involved regional lymph nodes is unknown.
10. DETAILED STAGING INFORMATION:

Based on the above information, the PRIMARY TUMOR is classified as:

TNM Scheme	FIGO Scheme	Definition	Macroscopic
T3c	IIIC		
peritoneal metastasis beyond		true	
pelvis measuring > 2 cm in greatest		dimension,	

THE REGIONAL LYMPH NODES are classified as:
NX (Nodal status cannot be assessed)

THE STATUS OF DISTANT TUMOR SITES is classified as:
M1 (Distant metastases are present) METASTATIC ADENOCARCINOMA IN PLEURAL EFFUSION

11. The FINAL AJCC/UICC/FIGO STAGE IS:
AJCC/UICC/FIGO

IV (Any T3A/MX/M1)

Source: NCI Genomic Data Commons file c9965510-c86a-47dd-86db-7c10fb2b2061 (TCGA-24-0979.3385E5B4-EBD4-4317-8805-EE6EA47A2E4A.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).